Somatic mutation profile of tumor specimen MMRF_1098_1_BM_CD138pos (aliquot MMRF_1098_1_BM_CD138pos_T1_KBS5U_L02852) from MMRF case MMRF_1098, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 49.8 years (18,175 days).
Specimen MMRF_1098_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) da7e3da2-43c3-4add-a784-ba9c0a744766.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1098_1_PB_WBC (Blood Derived Normal), aliquot MMRF_1098_1_PB_WBC_C3_KBS5U_L02864; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cd8ecf78-1db8-4007-b04c-2f6ae1fe3211

The open-access MAF lists 62 somatic variants for this specimen: 31 protein-altering or splice-affecting, 5 silent, 26 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, 3'UTR 9, Intron 8, Silent 5, 5'UTR 5, Frame Shift Del 3, Nonsense Mutation 2, 3'Flank 2, RNA 2, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAX | c.178C>T p.R60W | Missense Mutation (SNP) | VAF 9/157 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM122946, COSV52415839; called by muse, mutect2
- ARHGAP26 | c.1753C>T p.R585W | Missense Mutation (SNP) | VAF 18/145 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); catalogued as rs762950382, COSV50835493; called by muse, mutect2, varscan2
- DHX37 | c.1117G>A p.E373K | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs139345740; called by muse, mutect2, varscan2
- IGHV1-69D | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 40/69 reads (58%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs1367696485; called by mutect2, varscan2
- IGLV3-25 | c.250A>G p.S84G | Missense Mutation (SNP) | VAF 63/71 reads (89%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as rs1433743522; called by muse, varscan2
- IKBKB | c.511A>G p.K171E | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1217007648, COSV60595911, COSV60598768; called by muse, mutect2
- IKBKE | c.746C>A p.A249D | Missense Mutation (SNP) | VAF 32/61 reads (52%) | SIFT deleterious (0.05); PolyPhen benign (0.231); catalogued as COSV65624353; called by muse, mutect2, varscan2
- MAX | c.104G>A p.R35H | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52416276, COSV52416985, COSV52418829; called by muse, mutect2
- MUC5AC | c.12067C>T p.R4023W | Missense Mutation (SNP) | VAF 47/99 reads (47%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.98); catalogued as rs1320176639; called by muse, mutect2, varscan2
- NFKBIA | c.334C>T p.Q112* | Nonsense Mutation (SNP) | VAF 6/98 reads (6%) | catalogued as COSV53752585; called by muse, mutect2
- NGEF | c.1961G>A p.R654H | Missense Mutation (SNP) | VAF 52/130 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779013074, COSV50917161; called by muse, mutect2, varscan2
- NOVA1 | c.247A>T p.I83F | Missense Mutation (SNP) | VAF 11/160 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV99948721; called by muse, mutect2
- SLC45A3 | c.1049G>A p.G350D | Missense Mutation (SNP) | VAF 46/93 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV65655527; called by muse, mutect2, varscan2
- TBC1D16 | c.152G>T p.G51V | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs1375857714; called by muse, mutect2, varscan2
- TNFRSF14 | c.35G>A p.W12* | Nonsense Mutation (SNP) | VAF 47/91 reads (52%) | catalogued as rs768520625, COSV63186354; called by muse, mutect2, varscan2
- TOX3 | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 70/150 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.086); catalogued as rs369822258; called by muse, mutect2, varscan2
- TSC1 | c.2524C>A p.Q842K | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.868); catalogued as BM1382815, COSV100052365; called by muse, mutect2
- FRK | c.1354C>T p.L452F | Missense Mutation (SNP) | VAF 68/139 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- IGHG3 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 33/33 reads (100%) | SIFT tolerated (0.11); PolyPhen benign (0.439); called by muse, varscan2
- IGLC2 | c.239A>G p.K80R | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by mutect2, varscan2
- LTB | c.115A>G p.T39A | Missense Mutation (SNP) | VAF 68/124 reads (55%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); called by muse, varscan2
- RNF144B | c.-37G>C | Splice Region (SNP) | VAF 38/81 reads (47%) | called by muse, mutect2, varscan2
- SPTA1 | c.3977T>C p.I1326T | Missense Mutation (SNP) | VAF 25/221 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- SRL | c.1119_1121del p.E373del | In Frame Del (DEL) | VAF 67/139 reads (48%) | called by mutect2, pindel, varscan2
- TBL1Y | c.1442C>A p.T481N | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.418); called by muse, mutect2
- TRAF3 | c.1189_1190del p.I397Pfs*56 | Frame Shift Del (DEL) | VAF 8/78 reads (10%) | called by mutect2, pindel
- TRAF3 | c.1633_1634del p.N545Wfs*5 | Frame Shift Del (DEL) | VAF 14/96 reads (15%) | called by mutect2, pindel, varscan2
- TTN | c.87488G>C p.G29163A (on ENST00000591111; = p.G21739A on NM_003319.4) | Missense Mutation (SNP) | VAF 7/175 reads (4%) | PolyPhen benign (0.422); called by muse, mutect2
- YLPM1 | c.4333del p.V1445* | Frame Shift Del (DEL) | VAF 6/54 reads (11%) | called by mutect2, pindel
- YWHAE | c.569G>A p.R190H | Missense Mutation (SNP) | VAF 46/89 reads (52%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- ZNF254 | c.517A>G p.K173E | Missense Mutation (SNP) | VAF 88/191 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- ABCB6 | c.1530C>T p.L510= | Silent (SNP) | VAF 88/184 reads (48%) | catalogued as rs79405980, COSV54700206; called by muse, mutect2, varscan2
- EGLN2 | c.1113T>G p.T371= | Silent (SNP) | VAF 45/101 reads (45%) | called by muse, mutect2, varscan2
- IGHV1-69D | c.156T>A p.A52= | Silent (SNP) | VAF 55/107 reads (51%) | called by muse, mutect2
- IGHV4-34 | c.231C>T p.I77= | Silent (SNP) | VAF 52/57 reads (91%) | catalogued as rs770942985; called by muse, mutect2, varscan2
- MCM3AP | c.3655T>C p.L1219= | Silent (SNP) | VAF 44/85 reads (52%) | catalogued as rs1384990375; called by muse, mutect2, varscan2
- ACTB | c.-27-221C>G | Intron (SNP) | VAF 23/37 reads (62%) | catalogued as rs1451367586; called by muse, mutect2, varscan2
- AP001267.5 | c.-799+33187T>A | Intron (SNP) | VAF 66/164 reads (40%) | called by muse, mutect2, varscan2
- ATP2B2 | chr3:10325148 G>A | 3'Flank (SNP) | VAF 4/65 reads (6%) | called by muse, mutect2
- CDC40 | c.630+76T>G | Intron (SNP) | VAF 98/197 reads (50%) | called by muse, mutect2, varscan2
- CHIC1 | c.*3124T>G | 3'UTR (SNP) | VAF 18/84 reads (21%) | called by muse, mutect2, varscan2
- CNTN5 | c.*144A>G | 3'UTR (SNP) | VAF 91/198 reads (46%) | called by muse, mutect2, varscan2
- CREB3L2 | c.*4668G>A | 3'UTR (SNP) | VAF 67/161 reads (42%) | catalogued as rs574985667; called by muse, mutect2, varscan2
- CREB5 | c.-163G>C | 5'UTR (SNP) | VAF 5/67 reads (7%) | called by muse, mutect2
- DLX4 | c.481-82C>T | Intron (SNP) | VAF 6/63 reads (10%) | called by muse, mutect2
- FAM91A1 | c.810+122A>G | Intron (SNP) | VAF 7/13 reads (54%) | called by muse, mutect2, varscan2
- IL19 | c.363+210C>A | Intron (SNP) | VAF 12/146 reads (8%) | catalogued as rs1031015256; called by muse, mutect2
- KCNB2 | c.-65G>A | 5'UTR (SNP) | VAF 112/246 reads (46%) | called by muse, mutect2, varscan2
- KLKP1 | n.866C>A | RNA (SNP) | VAF 34/72 reads (47%) | called by muse, mutect2, varscan2
- LTB | c.162+136G>C | Intron (SNP) | VAF 37/83 reads (45%) | called by muse, varscan2
- METTL15P1 | n.649A>G | RNA (SNP) | VAF 58/141 reads (41%) | called by muse, mutect2, varscan2
- MT2A | c.*120G>T | 3'UTR (SNP) | VAF 36/78 reads (46%) | called by muse, mutect2
- NPSR1 | c.-126G>A | 5'UTR (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- PIKFYVE | c.*1979C>T | 3'UTR (SNP) | VAF 38/79 reads (48%) | called by muse, mutect2, varscan2
- POLR2H | c.-202A>C | 5'UTR (SNP) | VAF 5/79 reads (6%) | called by muse, mutect2
- PTPRR | c.*3C>T | 3'UTR (SNP) | VAF 19/151 reads (13%) | called by muse, mutect2, varscan2
- SCN2A | c.*493G>C | 3'UTR (SNP) | VAF 6/84 reads (7%) | called by muse, mutect2
- SYNPO | chr5:150657384 G>T | 3'Flank (SNP) | VAF 7/109 reads (6%) | called by muse, mutect2
- TDG | c.-112C>T | 5'UTR (SNP) | VAF 23/73 reads (32%) | called by muse, mutect2, varscan2
- THBD | c.*1228C>G | 3'UTR (SNP) | VAF 25/50 reads (50%) | called by muse, mutect2, varscan2
- TTC30A | c.*212G>A | 3'UTR (SNP) | VAF 51/98 reads (52%) | called by muse, mutect2, varscan2
- USP3 | c.1216-109G>A | Intron (SNP) | VAF 13/24 reads (54%) | called by muse, mutect2, varscan2
